TCGA case TCGA-DB-5276 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9d0c1552-00a7-4f0a-a04a-a82e721ee4e3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 32 years; Vital status: Alive.

Diagnoses (1)
1. Mixed glioma: ICD-O-3 morphology code: 9382/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 32.1 years (11,738 days); Year of diagnosis: 2007; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,218 days (6.1 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 12 days; Days to treatment end: 67 days; Treatment dose: 5,800 cGy; Course number: 1; Number of fractions: 29; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 12 days; Days to treatment end: 69 days; Number of cycles: 6; Treatment dose: 6,510 mg; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 69 days; Days to treatment end: 283 days; Number of cycles: 6; Treatment dose: 9,000 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Imatinib Mesylate; Initial disease status: Progressive Disease; Days to treatment start: 1,011 days (2.8 years); Days to treatment end: 1,189 days (3.3 years); Number of cycles: 6; Prescribed dose: 600; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Imatinib Mesylate; Initial disease status: Progressive Disease; Days to treatment start: 1,196 days (3.3 years); Days to treatment end: 1,342 days (3.7 years); Number of cycles: 5; Prescribed dose: 300; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.

Follow-up (2 entries)
- Days to follow up: 1,595 days (4.4 years); Disease response: Tumor Free.
- Days to follow up: 2,218 days (6.1 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Seizure.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DB-5276-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 1.3; Shortest dimension: 0.4.
  Slide TCGA-DB-5276-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-DB-5276-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-DB-5276-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DB-5276-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligoastrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: Tumor free; Tumor site: Supratentorial, Frontal Lobe; History seizures: Yes; History headaches: No; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes; Family history brain tumor: No; Inherited genetic syndrome indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Gleevec; Therapy regimen: Progression.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,218 days; disease-specific survival: no event (censored), 2,218 days; disease-free interval: no event (censored), 2,218 days; progression-free interval: no event (censored), 2,218 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DB-5276-01A-01D-1466-01): tumor purity 0.36, ploidy 2, whole-genome doublings 0.
